MMRF case MMRF_1295 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b381b197-292a-47ca-909c-be4b41d65a39

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.7 years (23,990 days); ISS stage: II; Days to last known disease status: 1,537 days (4.2 years); Days to last follow up: 1,537 days (4.2 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 282 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days; Days to treatment end: 381 days (1.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 23 days; Days to treatment end: 262 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 37 days; Days to treatment end: 282 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 418 days (1.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -12 (ECOG 0): M Protein 1.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1123 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.18 mg/dL; Immunoglobulin G 24.3 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.03 g/L; Beta 2 Microglobulin 3.3 µg/mL; Lactate Dehydrogenase 4.93 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 247 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.3 mmol/L; Albumin 34 g/L; Total Protein 7.6 g/dL; Glucose 6.88 mmol/L.
- Day 86 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.58 mg/dL; Immunoglobulin G 5.17 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 2.19 µg/mL; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 6.3 g/dL; Glucose 4.68 mmol/L.
- Day 177 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.39 mg/dL; Immunoglobulin G 4.24 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 2.03 µg/mL; Hemoglobin 7.63 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 5.17 mmol/L.
- Day 247 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 3.87 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 1.75 µg/mL; Hemoglobin 7.5 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.1 mmol/L; Albumin 36 g/L; Total Protein 5.9 g/dL; Glucose 5.78 mmol/L.
- Day 361 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 6.56 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 2 µg/mL; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.05 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 4.07 mmol/L.
- Day 446 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 5.85 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.13 mmol/L; Albumin 35 g/L; Total Protein 6.2 g/dL; Glucose 5.17 mmol/L.
- Day 538 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.35 mg/dL; Immunoglobulin G 5.2 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 1.89 µg/mL; Lactate Dehydrogenase 1.92 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.2 mmol/L; Albumin 33 g/L; Total Protein 6 g/dL; Glucose 6.49 mmol/L.
- Day 636 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.81 mg/dL; Immunoglobulin G 5.74 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 2.03 µg/mL; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.13 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 4.35 mmol/L.
- Day 720 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.93 mg/dL; Immunoglobulin G 5.06 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 2.02 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 6.2 g/dL; Glucose 4.35 mmol/L.
- Day 818 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.91 mg/dL; Immunoglobulin G 5.98 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 2.02 µkat/L; Hemoglobin 9.42 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.08 mmol/L; Albumin 35 g/L; Total Protein 6.5 g/dL; Glucose 3.69 mmol/L.
- Day 888: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.45 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 1.64 g/L; Immunoglobulin M 0.389 g/L; Beta 2 Microglobulin 2.16 µg/mL; Lactate Dehydrogenase 2.02 µkat/L; Hemoglobin 9.92 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 5.7 g/dL; Glucose 4.13 mmol/L.
- Day 989: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.732 mg/dL; Immunoglobulin G 6.57 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 2.18 µg/mL; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.15 mmol/L; Albumin 35 g/L; Total Protein 6.2 g/dL; Glucose 6.44 mmol/L.
- Day 1,096 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 13.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.792 mg/dL; Immunoglobulin G 7.24 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 2.66 µg/mL; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.08 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 5.23 mmol/L.
- Day 1,154 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 26.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.916 mg/dL; Immunoglobulin G 6.67 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.5 g/L; Beta 2 Microglobulin 2.52 µg/mL; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 9.42 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.05 mmol/L; Albumin 34 g/L; Total Protein 6.4 g/dL; Glucose 4.57 mmol/L.
- Day 1,259 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 40.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.558 mg/dL; Immunoglobulin G 4.61 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 2.08 µg/mL; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2 mmol/L; Albumin 32 g/L; Total Protein 5.6 g/dL; Glucose 4.9 mmol/L.
- Day 1,355 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 126 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.188 mg/dL; Immunoglobulin G 4.18 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 2.32 µg/mL; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.08 mmol/L; Albumin 29 g/L; Total Protein 5.4 g/dL; Glucose 5.12 mmol/L.
- Day 1,432 (ECOG 0): Hemoglobin 8.87 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 32 g/L; Total Protein 6.1 g/dL; Glucose 6.05 mmol/L.
- Day 1,537 (ECOG 0): Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 330 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.13 mmol/L; Albumin 30 g/L; Total Protein 6.4 g/dL; Glucose 5.94 mmol/L.

Other clinical attributes
- Day -12: Weight: 71 kg; Height: 160 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1295_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -12 days.
- Sample MMRF_1295_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -12 days.
